Somatic mutation profile of tumor specimen 0DUKH9 from CCDI case PBCLAI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.2 years (5,565 days).
Specimen 0DUKH9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f845bea-acfe-41fd-a995-f282a1354a23.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUKIN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a51e716-f25f-47b7-9419-f12c2b245591

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 2, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNA1 | c.715C>A p.R239S | Missense Mutation (SNP) | VAF 52/680 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104894348, CM940993, COSV101230079; ClinVar: pathogenic; called by muse, mutect2
- CD180 | c.807G>C p.K269N | Missense Mutation (SNP) | VAF 26/954 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2
- DSEL | c.1048C>T p.P350S | Missense Mutation (SNP) | VAF 113/801 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGEC1 | c.3326A>T p.D1109V | Missense Mutation (SNP) | VAF 34/768 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); called by muse, mutect2
- ZSCAN5A | c.400C>T p.H134Y | Missense Mutation (SNP) | VAF 135/540 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FGFR1OP2 | c.396+73T>C | Intron (SNP) | VAF 10/188 reads (5%) | catalogued as COSV99987084; called by muse, mutect2
- FRAS1 | c.5856+113A>T | Intron (SNP) | VAF 10/293 reads (3%) | called by muse, mutect2
- OR2AP1 | c.*96A>G | 3'UTR (SNP) | VAF 8/104 reads (8%) | catalogued as rs1012935800, COSV58726711; called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 26/242 reads (11%) | called by muse, varscan2
